TCGA case TCGA-DJ-A1QL — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e4b08e66-0772-4956-8670-e5c6553eecbe

Demographics
Sex at birth: male; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Papillary carcinoma, follicular variant: ICD-O-3 morphology code: 8340/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 70.4 years (25,713 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 535 days (1.5 years); Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Measurement unit: Centimeters; Tumor depth measurement: 1.8; Tumor length measurement: 2.1; Tumor width measurement: 1.8.
   Recorded as not given: adjuvant I-131 Radiation Therapy; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS; adjuvant Radiation, External Beam.

Follow-up (5 entries)
- Days to follow up: 207 days; Disease response: Tumor Free.
- Days to follow up: 219 days; Disease response: Tumor Free.
- Days to follow up: 535 days (1.5 years); Disease response: Tumor Free.
- Disease response: Complete Response; Timepoint: Within 3 Months of Surgery.
- Imaging type: Ultrasound; Imaging anatomic site: Lymph Node; Timepoint: Preoperative.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Nodular Hyperplasia.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DJ-A1QL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 370 mg.
  Slide TCGA-DJ-A1QL-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DJ-A1QL-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DJ-A1QL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Follicular (>= 99% follicular patterned); Laterality: Left lobe; Lymph nodes preop imaging: Yes; Lymph nodes examined: No; Genotypic analysis detected: No.
- Patient personal medical history thyroid gland disorder names: History thyroid disease: Nodular Hyperplasia.
- Follow-up form 1: I 131 radiation first treatment method: Patient did not receive I-131 treatment; Radiation therapy xrt method prep: Patient Did Not Receive Radiation Therapy; Clinical status within 3 mths surgery: No imaging evidence of disease; Tumor status: Tumor free.
- Follow-up form 1, New tumor: New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; I 131 radiation first treatment method: Patient did not receive I-131 treatment; Radiation therapy xrt method prep: Patient Did Not Receive External Radiation Therapy; Clinical status within 3 mths surgery: No imaging evidence of disease; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 535 days; disease-specific survival: no event (censored), 535 days; disease-free interval: no event (censored), 535 days; progression-free interval: no event (censored), 535 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DJ-A1QL-01A-11D-A14V-01): tumor purity 0.84, ploidy 2, whole-genome doublings 0.
